Somatic mutation profile of tumor specimen MP2PRT-PASWVK-TMP1-A (aliquot MP2PRT-PASWVK-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PASWVK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.4 years (2,342 days).
Specimen MP2PRT-PASWVK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59d23452-9a39-462d-b4ce-7c1b8087531a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASWVK-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASWVK-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b29f7426-5d32-4377-a5ee-cca8f9244334

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD1 | c.347C>T p.T116M | Missense Mutation (SNP) | VAF 104/467 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as rs142354133, CM081517, COSV63310993; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8B3 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs201831721; called by muse, mutect2
- CCDC166 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 20/624 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV101545870; called by muse, mutect2
- DLC1 | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 127/253 reads (50%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs370106953; called by muse, mutect2, varscan2
- DNAH10 | c.10628G>A p.R3543H (on ENST00000409039; = p.R3482H on NM_207437.3) | Missense Mutation (SNP) | VAF 201/429 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs199819171; called by muse, mutect2, varscan2
- FGFBP2 | c.301C>T p.R101C | Missense Mutation (SNP) | VAF 165/545 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs573280165; called by muse, mutect2, varscan2
- FRMD4B | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs200224295, COSV101273540; called by muse, mutect2, varscan2
- KANK4 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 118/301 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as rs150211365; called by muse, mutect2, varscan2
- KMT2D | c.14965C>T p.R4989W | Missense Mutation (SNP) | VAF 202/432 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369790149; called by muse, mutect2, varscan2
- SSBP4 | c.195C>T p.C65= | Splice Region (SNP) | VAF 152/343 reads (44%) | catalogued as rs140756470, COSV99049446; called by muse, mutect2, varscan2
- NPC1L1 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 79/185 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- NPNT | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 174/557 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PLXNB1 | c.6035T>C p.I2012T | Missense Mutation (SNP) | VAF 140/312 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PTCHD3 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 279/626 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAD54L | c.1326G>A p.M442I | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TBKBP1 | c.1552A>G p.K518E | Missense Mutation (SNP) | VAF 191/607 reads (31%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- TENM3 | c.7798T>A p.F2600I | Missense Mutation (SNP) | VAF 145/506 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH13 | c.588C>T p.S196= | Silent (SNP) | VAF 128/310 reads (41%) | catalogued as rs564006725, COSV51795148; called by muse, mutect2, varscan2
- LDLRAD1 | c.153G>A p.A51= | Silent (SNP) | VAF 160/338 reads (47%) | catalogued as rs370365819; called by muse, mutect2, varscan2
- MUC2 | c.2349C>T p.F783= | Silent (SNP) | VAF 91/234 reads (39%) | catalogued as rs762811609; called by muse, mutect2, varscan2
- PCDHB13 | c.1737G>A p.A579= | Silent (SNP) | VAF 237/620 reads (38%) | called by muse, mutect2, varscan2
- ZNF750 | c.1614G>A p.A538= | Silent (SNP) | VAF 153/578 reads (26%) | catalogued as rs1379427763; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1343G>A | Intron (SNP) | VAF 174/377 reads (46%) | catalogued as COSV63751101, COSV63752792; called by muse, mutect2, varscan2
